Somatic mutation profile of tumor specimen ALCH-B2DN-TTP1-A (aliquot ALCH-B2DN-TTP1-A-1-0-D-A77J-36) from ALCHEMIST case ALCH-B2DN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.5 years (26,474 days).
Specimen ALCH-B2DN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ad3eb0d-38f2-423c-8bbc-6b574837104b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2DN-NB1-A (Blood Derived Normal), aliquot ALCH-B2DN-NB1-A-1-0-D-A77J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/076d77c5-a4cb-46df-89d0-2fafa1d0621b

The open-access MAF lists 118 somatic variants for this specimen: 72 protein-altering or splice-affecting, 30 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 30, Nonsense Mutation 6, Intron 6, 3'UTR 4, 5'UTR 4, Splice Region 3, Splice Site 2, Frame Shift Del 1, Translation Start Site 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.2680G>A p.D894N | Missense Mutation (SNP) | VAF 24/138 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59214349, COSV59219610; called by muse, mutect2
- AMPH | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272402161, COSV57740359; called by muse, mutect2, varscan2
- AMY1C | c.980T>C p.I327T | Missense Mutation (SNP) | VAF 34/780 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV64407320; called by muse, mutect2
- ARID1A | c.6625C>T p.Q2209* | Nonsense Mutation (SNP) | VAF 8/102 reads (8%) | catalogued as COSV61372280; called by muse, mutect2
- BRD3 | c.1136A>G p.D379G | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57703482; called by muse, mutect2, varscan2
- CPT1C | c.2306A>T p.K769M | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs1021039766; called by muse, mutect2, varscan2
- DDI1 | c.277C>A p.R93S | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV56386828; called by muse, mutect2, varscan2
- DSG1 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57139144; called by muse, mutect2
- GAB2 | c.1459G>C p.D487H (on ENST00000361507 / NM_080491.3; = p.D449H on NM_012296.3) | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); catalogued as COSV60868077; called by muse, mutect2
- HSP90AB1 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100807040; called by muse, mutect2, varscan2
- KIF16B | c.3731C>T p.P1244L | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100734807; called by muse, mutect2
- LGI1 | c.431+1G>T p.X144_splice | Splice Site (SNP) | VAF 25/190 reads (13%) | catalogued as CS071239; called by muse, mutect2, varscan2
- LRP12 | c.1990A>G p.M664V | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1242163059; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58187345; called by muse, mutect2, varscan2
- MAP6 | c.119C>G p.P40R | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs771037189; called by muse, varscan2
- NAV3 | c.3571C>A p.P1191T | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV57119984; called by muse, mutect2, varscan2
- NCK1 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 26/237 reads (11%) | catalogued as COSV56637012, COSV99999376; called by muse, mutect2, varscan2
- NEIL3 | c.989A>G p.N330S | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370343477; called by muse, mutect2, varscan2
- OGDHL | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV65101725; called by muse, mutect2, varscan2
- PCDHGA10 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 20/145 reads (14%) | catalogued as COSV53966962, COSV54011010; called by muse, mutect2, varscan2
- PCDHGB1 | c.1133T>A p.V378E | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99534888; called by muse, mutect2, varscan2
- POTEC | c.103T>A p.C35S | Missense Mutation (SNP) | VAF 39/376 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); catalogued as COSV100743728; called by muse, mutect2, varscan2
- RASSF9 | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 24/234 reads (10%) | catalogued as COSV63433125; called by muse, mutect2
- SF1 | c.495G>C p.K165N | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57111462, COSV99918530; called by muse, varscan2
- SLC2A11 | c.1291-4G>A | Splice Region (SNP) | VAF 4/42 reads (10%) | catalogued as rs201451731; called by muse, varscan2
- STK11 | c.874T>G p.Y292D | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.449); catalogued as COSV58829993; called by muse, varscan2
- TARS1 | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 39/330 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV99465622; called by muse, mutect2, varscan2
- TM4SF5 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs374954745; called by muse, mutect2, varscan2
- UBOX5 | c.1529G>C p.R510P | Missense Mutation (SNP) | VAF 80/552 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99417888; called by muse, mutect2, varscan2
- ZSCAN1 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.456); catalogued as rs779775559, COSV56607313; called by muse, mutect2, varscan2
- ABCE1 | c.1561G>T p.D521Y | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ACCSL | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ADGRD2 | c.2800G>A p.E934K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- APCDD1L | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, mutect2
- BSN | c.2224C>T p.P742S | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C1orf35 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- C9orf24 | c.396+5C>A | Splice Region (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2, varscan2
- CD200R1 | c.740A>T p.Y247F (on ENST00000471858 / NM_170780.3; = p.Y270F on NM_138806.4) | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- CMA1 | c.534C>A p.F178L | Missense Mutation (SNP) | VAF 45/239 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- COL3A1 | c.1253C>A p.P418Q | Missense Mutation (SNP) | VAF 55/391 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- COP1 | c.874G>C p.D292H | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- CYP4F2 | c.119C>A p.A40D | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DAAM1 | c.1976T>C p.F659S | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- FAM126A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 34/224 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- GNA12 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- GORASP1 | c.768C>T p.A256= | Splice Region (SNP) | VAF 20/290 reads (7%) | called by muse, mutect2
- HACE1 | c.497C>A p.T166K | Missense Mutation (SNP) | VAF 11/372 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- IRS2 | c.1223G>A p.G408D | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- IVL | c.406C>A p.Q136K | Missense Mutation (SNP) | VAF 43/390 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- LRRK1 | c.3623A>T p.H1208L | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MTF2 | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NTRK3 | c.2176-1G>T p.X726_splice (on ENST00000360948 / NM_001012338.2; = p.X712_splice on NM_002530.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 30/215 reads (14%) | called by muse, mutect2, varscan2
- OGT | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- OR2M5 | c.399del p.N134Ifs*3 | Frame Shift Del (DEL) | VAF 53/318 reads (17%) | called by mutect2, pindel, varscan2
- OR8K1 | c.398G>C p.C133S | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- PDE11A | c.235A>T p.N79Y | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRSS56 | c.664G>T p.G222* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- RYR2 | c.9494C>T p.A3165V | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SACS | c.5000C>T p.A1667V | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SAGE1 | c.2700C>A p.H900Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- SALL1 | c.1026C>A p.N342K | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SCP2 | c.1451C>T p.S484L | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- SHPK | c.1249C>G p.Q417E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOX15 | c.638C>G p.P213R | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- STK38L | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 12/147 reads (8%) | called by muse, mutect2
- THAP7 | c.124A>C p.N42H | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRIM58 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.326); called by muse, mutect2
- TRNT1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); called by muse, mutect2
- TRPM3 | c.925G>A p.V309M (on ENST00000357533 / NM_001366142.2; = p.V154M on NM_020952.6) | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- TTN | c.18709A>C p.K6237Q (on ENST00000591111; = p.K5310Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | PolyPhen benign (0.2); called by muse, mutect2, varscan2
- UNC5D | c.809G>C p.R270T | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2
- ZNF552 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.838); called by mutect2, varscan2
- ALDH1A3 | c.1356G>A p.L452= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as rs1199719762; called by muse, mutect2, varscan2
- C8B | c.459A>G p.A153= | Silent (SNP) | VAF 48/409 reads (12%) | called by muse, mutect2, varscan2
- CELSR1 | c.3471G>A p.T1157= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs186474366; called by muse, mutect2
- DKK3 | c.790C>A p.R264= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as COSV100484917; called by muse, mutect2
- DSG1 | c.447T>C p.D149= | Silent (SNP) | VAF 61/405 reads (15%) | called by muse, mutect2, varscan2
- EHD4 | c.918G>T p.L306= | Silent (SNP) | VAF 44/314 reads (14%) | called by muse, mutect2, varscan2
- FOSB | c.96C>T p.F32= | Silent (SNP) | VAF 17/162 reads (10%) | called by muse, mutect2, varscan2
- GNAT3 | c.909C>A p.I303= | Silent (SNP) | VAF 20/127 reads (16%) | called by muse, mutect2, varscan2
- GNB3 | c.783G>A p.L261= | Silent (SNP) | VAF 16/300 reads (5%) | called by muse, mutect2
- HACE1 | c.498A>T p.T166= | Silent (SNP) | VAF 11/373 reads (3%) | called by muse, mutect2
- HOXA5 | c.84T>C p.S28= | Silent (SNP) | VAF 26/217 reads (12%) | called by muse, mutect2, varscan2
- KIRREL2 | c.1818C>T p.V606= | Silent (SNP) | VAF 7/160 reads (4%) | catalogued as rs896403514, COSV52874865; called by muse, mutect2
- KRT7 | c.684C>G p.L228= | Silent (SNP) | VAF 11/125 reads (9%) | called by muse, mutect2
- LTBR | c.351A>T p.T117= | Silent (SNP) | VAF 25/245 reads (10%) | called by muse, mutect2, varscan2
- MPEG1 | c.1740C>T p.S580= | Silent (SNP) | VAF 12/125 reads (10%) | catalogued as rs186140164, COSV57092154; called by muse, mutect2, varscan2
- MUC16 | c.29052C>A p.T9684= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV67492363; called by muse, mutect2, varscan2
- NAV1 | c.4509C>T p.P1503= | Silent (SNP) | VAF 31/209 reads (15%) | catalogued as rs769624749, COSV55224521; called by muse, mutect2, varscan2
- NAV3 | c.4083G>A p.P1361= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as rs796840739, COSV57088121; called by muse, mutect2
- NBAS | c.5166A>G p.R1722= | Silent (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- PCDHGA5 | c.726C>T p.F242= | Silent (SNP) | VAF 20/164 reads (12%) | called by muse, mutect2, varscan2
- PIK3CG | c.660C>A p.I220= | Silent (SNP) | VAF 30/220 reads (14%) | called by muse, mutect2, varscan2
- PLCD4 | c.255C>T p.L85= | Silent (SNP) | VAF 29/269 reads (11%) | called by muse, mutect2, varscan2
- PPP1R26 | c.2637G>A p.R879= | Silent (SNP) | VAF 14/157 reads (9%) | catalogued as rs1185745708; called by muse, mutect2, varscan2
- PTCD2 | c.411G>A p.V137= | Silent (SNP) | VAF 20/236 reads (8%) | called by muse, mutect2
- RYR1 | c.2229C>T p.I743= | Silent (SNP) | VAF 14/137 reads (10%) | called by muse, mutect2, varscan2
- ST8SIA1 | c.420G>C p.V140= | Silent (SNP) | VAF 23/226 reads (10%) | catalogued as rs774709345; called by muse, mutect2
- SYNPO2 | c.591T>G p.V197= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs767183818; called by muse, mutect2, varscan2
- SYT14 | c.732A>T p.G244= | Silent (SNP) | VAF 30/200 reads (15%) | called by muse, mutect2, varscan2
- TNC | c.3396G>A p.P1132= | Silent (SNP) | VAF 19/165 reads (12%) | catalogued as rs750372440, COSV100406447; called by muse, mutect2, varscan2
- UGT2A2 | c.246G>A p.V82= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
- BRCA1 | c.*704G>A | 3'UTR (SNP) | VAF 4/32 reads (13%) | catalogued as rs1325204994; called by mutect2, varscan2
- BRWD3 | c.1127+26A>G | Intron (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2
- CSMD3 | c.*2G>A | 3'UTR (SNP) | VAF 24/196 reads (12%) | catalogued as rs1239977200, COSV99849983; called by muse, mutect2, varscan2
- DNMT1 | c.4245+32C>T | Intron (SNP) | VAF 31/195 reads (16%) | catalogued as rs374484590; called by muse, mutect2, varscan2
- DPY19L2P1 | n.1811+1649C>T | Intron (SNP) | VAF 8/130 reads (6%) | catalogued as rs1246678298; called by muse, mutect2
- ERFE | c.*1322G>A | 3'UTR (SNP) | VAF 15/96 reads (16%) | catalogued as rs945573147; called by muse, mutect2, varscan2
- GATM | c.288+24C>T | Intron (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2, varscan2
- GMPR2 | c.857+58G>C | Intron (SNP) | VAF 13/87 reads (15%) | catalogued as rs1039642339; called by muse, mutect2, varscan2
- ILK | c.89+39G>T | Intron (SNP) | VAF 29/203 reads (14%) | called by muse, mutect2, varscan2
- MPDU1 | c.*122G>A | 3'UTR (SNP) | VAF 42/524 reads (8%) | called by muse, mutect2
- NUDT1 | c.-14G>A | 5'UTR (SNP) | VAF 22/213 reads (10%) | called by muse, mutect2, varscan2
- OR51F5P | n.478C>A | RNA (SNP) | VAF 20/119 reads (17%) | called by mutect2, varscan2
- RAB27A | c.-14C>T | 5'UTR (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2, varscan2
- RBM11 | c.-2G>A | 5'UTR (SNP) | VAF 22/193 reads (11%) | called by muse, mutect2, varscan2
- SLC1A2 | chr11:35419970 C>T | 5'Flank (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99555264; called by muse, mutect2
- ZNF98 | c.-34T>A | 5'UTR (SNP) | VAF 28/194 reads (14%) | called by muse, mutect2, varscan2
